Somatic mutation profile of tumor specimen TCGA-VP-A875-01A (aliquot TCGA-VP-A875-01A-31D-A34U-08) from TCGA case TCGA-VP-A875, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.7 years (24,742 days).
Specimen TCGA-VP-A875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d55741ce-985c-4096-804e-35a4b9291a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A875-10A (Blood Derived Normal), aliquot TCGA-VP-A875-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99ea061f-57cd-400d-9f72-11a390c001d4

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137852573, CM920073, COSV65954700; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.5674C>T p.R1892* (on ENST00000303395 / NM_001202435.3; = p.R1881* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs794726739, CM024313, CM162662, COSV100318718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99574612; called by muse, mutect2, varscan2
- AFG3L2 | c.640T>C p.F214L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302028; called by muse, mutect2, varscan2
- AKAP1 | c.2666A>G p.E889G | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100533032; called by muse, mutect2, varscan2
- BTBD1 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as COSV99915572; called by muse, mutect2, varscan2
- CACNA1S | c.1872C>G p.I624M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100755165; called by muse, mutect2, varscan2
- CXXC5 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100210769, COSV56793147; called by muse, mutect2, varscan2
- F11 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99251661; called by muse, mutect2, varscan2
- FNDC3B | c.3019A>G p.I1007V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs910314457, COSV100394447; called by muse, mutect2, varscan2
- GPR84 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99910082, COSV99910105; called by muse, mutect2, varscan2
- GRIA1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs143445023; called by muse, mutect2, varscan2
- LAMB4 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs138272045; called by muse, mutect2, varscan2
- LMBR1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763139081; called by muse, mutect2, varscan2
- NAGA | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101124160; called by mutect2, varscan2
- NELL1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs370190924; called by muse, mutect2, varscan2
- NT5DC2 | c.1058T>A p.V353E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100195156; called by muse, mutect2, varscan2
- PCDHB2 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as rs1296663897, COSV99165710; called by muse, mutect2
- PER1 | c.3458C>T p.T1153I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100424668; called by muse, varscan2
- SEC14L5 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs202231927; called by muse, mutect2, varscan2
- ST18 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs764596167, COSV99387837, COSV99390232; called by muse, mutect2, varscan2
- THSD7A | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1209387305, COSV70263944; called by muse, mutect2, varscan2
- VPS13B | c.7340G>C p.G2447A | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100662554; called by muse, mutect2, varscan2
- SLC37A1 | c.1357del p.S453Vfs*2 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ACTB | c.327C>T p.P109= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs781554752, COSV100079751; called by muse, mutect2, varscan2
- ATP1A3 | c.2895G>A p.T965= (on ENST00000545399 / NM_001256214.2; = p.T952= on NM_152296.5) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs148292376; ClinVar: likely benign; called by muse, mutect2
- CACNA1S | c.1815C>T p.I605= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs757733492, COSV100755166; called by muse, mutect2, varscan2
- CACNA1S | c.1653C>T p.S551= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100755167; called by muse, mutect2, varscan2
- CPN1 | c.1353G>A p.R451= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs778895556, COSV100962659; called by muse, mutect2, varscan2
- IMPG2 | c.471A>G p.E157= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99515911; called by muse, mutect2, varscan2
- NYAP2 | c.954G>T p.L318= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99797425; called by muse, mutect2, varscan2
- PEX5L | c.273G>A p.S91= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs1344594831, COSV99829241; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1569G>A p.P523= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs772011693, COSV54759349, COSV99770212; called by muse, mutect2, varscan2
- SLC25A46 | c.859C>T p.L287= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1180903647, COSV100582620; called by muse, mutect2, varscan2
